Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A923, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A923-01A (Primary Tumor).

Collect date:

ICD 0-3

Adenocarcinoma, tubular
8/21/13

Site: Body of stomach C16.2
8/23/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

"1-TOTAL GASTRECTOMY - DI:

POORLY DIFFERENTIATED TUBULAR ADENOCARCINOMA (LAUREN
INTESTINAL TYPE), INVASIVE TO SEROSA AND ADJACENT FAT TISSUE.

PRESENCE OF LYMPHATIC INVASION.

PRESENCE OF PERINEURAL INVASION.

METASTASIS IN 1 OF 9 LYMPH NODES FROM LESSER CURVATURE (1/9),

AND IN 3 OF 3 LYMPH NODES CLOSE TO GASTRIC WALL (3/3). TOTAL: 4/12,

CAPSULAR TRANSPOSITION PRESENT.

SURGICAL MARGINS UNINVOLVED BY NEOPLASIA.

PATTERN OF INVASION: INFILTRATIVE.

PRESENCE OF ULCERATION.

2- SPLEEN:

CAPSULAR FIBROUS NODULES.

REACTIVE WHITE PULP.

UNINVOLVED BY NEOPLASIA.

3- GALLBLADDER:

LITHIASIC CHRONIC CHOLECYSTITIS.

UNINVOLVED BY NEOPLASIA.

4- ESOPHAGEAL MARGIN:

UNINVOLVED BY NEOPLASIA."

Version	1.0	11/5/13	Yes	No
Regulatory Information				
Product Name/ID				
Product Description				
Product History				
Product Status				
Product Date				
Product Location				
Product Quantity				
Product Price				
Product Weight				
Product Volume				
Product Length				
Product Width				
Product Height				
Product Material				
Product Color				
Product Texture				
Product Odor				
Product Taste				
Product Sound				
Product Smell				
Product Touch				
Product Feel				
Product Look				
Product Sound				
Product Smell				
Product Touch				
Product Feel				
Product Look				

Source: NCI Genomic Data Commons file 2f8de134-983f-4a03-88ac-c0dc66980745 (TCGA-VQ-A923.F6AAFC21-095D-43E1-B78E-C0E85E3956A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).